Somatic mutation profile of tumor specimen TCGA-L5-A43E-01A (aliquot TCGA-L5-A43E-01A-11D-A247-09) from TCGA case TCGA-L5-A43E, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 74.3 years (27,143 days).
Specimen TCGA-L5-A43E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a02f888-1d2b-490d-b0b3-7e3cd1dfe159.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A43E-10A (Blood Derived Normal), aliquot TCGA-L5-A43E-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bca58273-f443-414b-b725-71a02ad87b65

The open-access MAF lists 162 somatic variants for this specimen: 119 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 40, Nonsense Mutation 4, Splice Site 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 10/15 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACBD3 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs750315321; called by muse, mutect2, varscan2
- AIFM1 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54856827, COSV54856953; called by muse, mutect2, varscan2
- ASB15 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as rs952485463, COSV51924713; called by muse, mutect2, varscan2
- AZU1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777566662; called by muse, mutect2, varscan2
- CCDC60 | c.1405T>C p.F469L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.352); catalogued as rs369830128; called by muse, mutect2, varscan2
- CCKBR | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as rs760799719, COSV58105659; called by muse, mutect2, varscan2
- CDH22 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs376488565; called by muse, mutect2
- CNTNAP5 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448342066, COSV70491153; called by muse, mutect2, varscan2
- CSF3R | c.2237C>A p.T746N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100117866; called by muse, mutect2, varscan2
- CXCR5 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764867894; called by muse, mutect2, varscan2
- DCAF12L2 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100758799, COSV63581446, COSV63581842; called by muse, mutect2, varscan2
- DCC | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.455); catalogued as COSV59099209; called by muse, mutect2, varscan2
- DENND2A | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs372731585; called by muse, mutect2
- DGKI | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772476015, COSV99935804; called by muse, mutect2, varscan2
- DNAH10 | c.6353C>T p.S2118L (on ENST00000409039; = p.S2057L on NM_207437.3) | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1018646580, COSV68993704; called by muse, mutect2, varscan2
- DNALI1 | c.725G>A p.R242Q (on ENST00000296218; = p.R220Q on NM_003462.5) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.476); catalogued as rs200945209; called by muse, mutect2, varscan2
- FANCM | c.3616C>T p.Q1206* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV57505907; called by muse, mutect2, varscan2
- GDF7 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1457114719; called by muse, mutect2, varscan2
- GRID1 | c.1594T>G p.F532V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100023649; called by muse, mutect2, varscan2
- GRIK3 | c.2236G>A p.V746I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs142411639; called by mutect2, varscan2
- GRIK3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100901466; called by muse, mutect2, varscan2
- HCN2 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52114033; called by muse, mutect2, varscan2
- HMCN1 | c.13000G>A p.V4334I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as rs1327271424, COSV54936423; called by muse, mutect2, varscan2
- IGHV3-21 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as rs200625829; called by muse, mutect2, varscan2
- IRAK4 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71210570; called by muse, mutect2, varscan2
- JAKMIP3 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs374337157; called by muse, varscan2
- KCNJ4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416311952, COSV100341106, COSV100341516; called by muse, mutect2, varscan2
- KCNK13 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs766324856, COSV56410212; called by muse, mutect2, varscan2
- KMT2D | c.11905C>T p.Q3969* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56407082; called by muse, mutect2, varscan2
- KMT2D | c.8167G>A p.E2723K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1247064603, COSV99981619; called by muse, mutect2, varscan2
- LAMA5 | c.5041G>A p.V1681M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs147438795, COSV53352683; called by muse, mutect2, varscan2
- LRP1B | c.5115-2A>C p.X1705_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101254728, COSV101262445, COSV67283735; called by muse, mutect2, varscan2
- LRP2 | c.5760C>A p.H1920Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV55556081; called by muse, mutect2, varscan2
- LRRC7 | c.1507G>C p.D503H (on ENST00000651989 / NM_001370785.2; = p.D470H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50548169, COSV50647007; called by muse, mutect2, varscan2
- MAGEE1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs374134344, COSV63911648; called by muse, mutect2, varscan2
- MATK | c.311C>T p.A104V (on ENST00000310132 / NM_139355.3; = p.A105V on NM_002378.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.411); catalogued as rs373715019; called by muse, mutect2
- MDGA1 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs746453937, COSV51796966; called by muse, mutect2, varscan2
- MMP16 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54152643; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>G p.K731R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- NALCN | c.1283T>G p.L428R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99218656; called by muse, mutect2, varscan2
- NLGN4X | c.445T>G p.L149V | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52026784; called by muse, mutect2, varscan2
- NMNAT1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as COSV65882977; called by muse, mutect2, varscan2
- NOX4 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99632407; called by muse, mutect2
- OLFM4 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as rs750555521, COSV99524180; called by muse, mutect2, varscan2
- OR14A16 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62927451; called by muse, mutect2, varscan2
- OR52E2 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100384861; called by muse, mutect2, varscan2
- OR52E8 | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV66211375; called by mutect2, varscan2
- OR8K3 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV57131104; called by muse, mutect2, varscan2
- PCDH15 | c.4199G>A p.R1400K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as COSV100221551; called by muse, mutect2, varscan2
- PCLO | c.9202A>C p.M3068L | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV100433824; called by muse, mutect2, varscan2
- PER1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs377111904; called by muse, mutect2, varscan2
- PRKD1 | c.2662A>C p.S888R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.031); catalogued as COSV100121560, COSV59578586; called by muse, mutect2, varscan2
- RECQL | c.1355A>G p.K452R | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577044266; called by muse, mutect2, varscan2
- RGS12 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs1227857970; called by muse, mutect2, varscan2
- RP1 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99606069, COSV99609091; called by muse, mutect2, varscan2
- SFRP1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs1209491334, COSV55172553; called by muse, mutect2
- SIRPB2 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs763155095, COSV63125666; called by muse, mutect2, varscan2
- SPTA1 | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV63752423, COSV63761847; called by muse, mutect2, varscan2
- STXBP5L | c.3413G>A p.R1138H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs778813739, COSV56497930; called by muse, mutect2, varscan2
- SYBU | c.190C>T p.R64C (on ENST00000276646 / NM_001099754.2; = p.R63C on NM_017786.6) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs760606239, COSV52619292; called by muse, mutect2, varscan2
- TNR | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144730675, COSV54920473, COSV99691507; called by muse, mutect2, varscan2
- TNXB | c.5912G>A p.R1971H (on ENST00000647633; = p.R1724H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as rs371138982; called by muse, mutect2, varscan2
- TPTE2 | c.1524T>G p.I508M (on ENST00000400230 / NM_199254.2; = p.I431M on NM_130785.3) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs780874714, COSV55027931; called by muse, mutect2, varscan2
- TRIML2 | c.1252A>G p.S418G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV58714802, COSV58718334; called by muse, mutect2, varscan2
- TTN | c.34699G>T p.V11567L (on ENST00000591111; = p.V10640L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | PolyPhen benign (0.003); catalogued as rs1377047166; called by muse, mutect2, varscan2
- TTN | c.12995A>T p.K4332M (on ENST00000591111; = p.K4286M on NM_003319.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV60212933; called by muse, mutect2, varscan2
- USH2A | c.4724A>C p.K1575T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100239420; called by muse, mutect2, varscan2
- VIP | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65889295, COSV65889370; called by muse, mutect2, varscan2
- ZC3H12C | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs769365245, COSV53713163; called by muse, mutect2, varscan2
- ZIC4 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67172353; called by muse, mutect2, varscan2
- ZNF208 | c.3062A>C p.K1021T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as COSV68109282; called by muse, mutect2, varscan2
- ZNF568 | c.1063A>C p.I355L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV61741819; called by muse, mutect2
- ABHD8 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACKR1 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ASXL3 | c.1293A>T p.K431N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- BAZ2B | c.5534A>G p.K1845R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CRISPLD1 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CSRNP1 | c.200T>G p.F67C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DACH2 | c.982T>G p.L328V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DCSTAMP | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DNAH9 | c.4226T>C p.L1409P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDNRB | c.284C>T p.P95L (on ENST00000377211 / NM_001201397.1; = p.P5L on NM_000115.5) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVC | c.1550T>G p.V517G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM184A | c.2665_2668del p.E889Ffs*8 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- GPAM | c.1433A>T p.K478M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- HOOK1 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- HYKK | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IRAK4 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.8072G>A p.G2691E (on ENST00000360013 / NM_001024660.4; = p.G994E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNMA1 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRBA | c.2044A>T p.N682Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP12 | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MARCO | c.473A>C p.H158P | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBPF15 | c.1202T>G p.I401S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NETO1 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- NLRP12 | c.3084A>C p.K1028N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- OR10G8 | c.764T>A p.L255H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PCDH10 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.413); called by muse, mutect2
- PEG3 | c.3028T>G p.L1010V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PKHD1L1 | c.5440G>A p.V1814I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PPP1R3A | c.1594A>C p.K532Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by mutect2, varscan2
- PREX2 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN10A | c.5022dup p.P1675Afs*5 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- SLCO6A1 | c.1732T>G p.L578V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SMC2 | c.2108C>G p.A703G | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SNRNP200 | c.6007C>T p.Q2003* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- SORCS1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); called by mutect2, varscan2
- SPANXB1 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TLR2 | c.2014T>G p.L672V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TRIM42 | c.2112G>T p.K704N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.52852G>T p.A17618S (on ENST00000591111; = p.A10194S on NM_003319.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.34492C>T p.P11498S (on ENST00000591111; = p.P12726S on NM_001267550.2) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | PolyPhen benign (0.116); called by mutect2, varscan2
- UNC5C | c.2327A>C p.N776T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF215 | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ZNF648 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF681 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by mutect2, varscan2
- ZNF763 | c.449A>C p.K150T (on ENST00000358987 / NM_001367172.2; = p.K153T on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ACSM5 | c.1413C>T p.N471= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs557422368; called by muse, mutect2, varscan2
- ADCY9 | c.2622G>A p.S874= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1436665952, COSV53576565; called by muse, mutect2, varscan2
- ANKRD6 | c.276G>A p.A92= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs772789950; called by muse, varscan2
- AP5Z1 | c.591C>T p.G197= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1210981615; called by muse, mutect2, varscan2
- ATP4A | c.759C>T p.I253= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs149356804; called by muse, mutect2
- ATXN7L3 | c.345C>A p.I115= | Silent (SNP) | VAF 22/31 reads (71%) | called by muse, mutect2, varscan2
- CCT8L2 | c.1386C>T p.D462= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs370876356; called by muse, mutect2, varscan2
- CDH12 | c.2019C>T p.F673= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs775446101, COSV66385898; called by muse, mutect2, varscan2
- CNTNAP2 | c.2319A>T p.G773= | Silent (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.900A>G p.E300= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- EFR3A | c.57G>A p.L19= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99603740; called by muse, mutect2, varscan2
- GHSR | c.336C>T p.G112= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- GPR87 | c.669C>T p.I223= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs149315251; called by mutect2, varscan2
- GUCY2F | c.912C>A p.L304= | Silent (SNP) | VAF 24/28 reads (86%) | called by muse, mutect2, varscan2
- IPO5 | c.1017C>A p.G339= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- KIDINS220 | c.3273G>A p.A1091= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs778534103, COSV56753246; called by muse, mutect2, varscan2
- KIR3DL1 | c.588C>T p.Y196= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs747672880; called by muse, mutect2
- KLHL18 | c.462G>C p.V154= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1242460940; called by muse, mutect2
- LHFPL3 | c.150C>T p.G50= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV67810279; called by muse, mutect2, varscan2
- LRRC8C | c.1956C>T p.I652= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV65001286; called by muse, mutect2, varscan2
- MAN2B1 | c.501C>T p.A167= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- MISP | c.345C>T p.D115= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs777876767; called by muse, mutect2
- MYH4 | c.1581C>T p.I527= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55122308; called by mutect2, varscan2
- NBEA | c.2916C>T p.N972= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- PCDH10 | c.1464C>T p.T488= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1293957400; called by muse, mutect2, varscan2
- PCLO | c.5877T>G p.S1959= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- PLXNA2 | c.639C>T p.L213= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1255719845; called by muse, mutect2, varscan2
- PRAMEF5 | c.354A>G p.E118= | Silent (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- RET | c.2898C>T p.T966= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs373693875; ClinVar: likely benign; called by muse, mutect2, varscan2
- SACS | c.13584T>G p.A4528= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- SHANK1 | c.660G>A p.A220= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs775556161, COSV53246569; called by muse, mutect2, varscan2
- SULT4A1 | c.45C>T p.F15= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV50780768, COSV50782499; called by muse, mutect2, varscan2
- TIAM1 | c.1134G>A p.A378= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs374340137; called by muse, mutect2, varscan2
- TTLL8 | c.1353C>T p.N451= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs766668436; called by mutect2, varscan2
- TTN | c.36645C>T p.N12215= (on ENST00000591111; = p.N4791= on NM_003319.4) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs559906667, COSV100601664; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC5D | c.1785T>C p.S595= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV54792158, COSV54833339; called by muse, mutect2, varscan2
- USP16 | c.2223C>G p.L741= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54505501; called by muse, mutect2, varscan2
- WDR33 | c.2166G>A p.P722= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs764039105; called by muse, mutect2, varscan2
- ZNF208 | c.288A>G p.Q96= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- ZNF461 | c.471A>G p.Q157= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV64452716; called by muse, mutect2, varscan2
- DCHS2 | n.6054T>G | RNA (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- NRG1 | c.701-4796A>T | Intron (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- OTUD6B | c.-9C>T | 5'UTR (SNP) | VAF 16/60 reads (27%) | catalogued as rs769247242; called by muse, mutect2, varscan2
